Somatic mutation profile of tumor specimen MMRF_2801_1_BM_CD138pos (aliquot MMRF_2801_1_BM_CD138pos_T1_KHS5U_L15737) from MMRF case MMRF_2801, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,054 days).
Specimen MMRF_2801_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a38c5413-2a76-4a06-b737-a3a331828885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2801_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2801_1_PB_WBC_C3_KHS5U_L15781; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aca11e9d-2e89-4b3e-b150-d5c05267968e

The open-access MAF lists 96 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 28, Missense Mutation 23, Intron 14, Nonsense Mutation 5, Silent 5, RNA 4, Splice Site 4, Splice Region 3, 3'Flank 3, 5'UTR 3, 5'Flank 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1186448117; called by muse, mutect2, varscan2
- ARID2 | c.2800C>T p.Q934* | Nonsense Mutation (SNP) | VAF 115/285 reads (40%) | catalogued as COSV57607212; called by mutect2, varscan2
- BOD1L1 | c.3119C>T p.S1040L | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs771870244; called by muse, mutect2
- DHX37 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs751307460, COSV100439603; called by muse, mutect2, varscan2
- FAP | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs760491232; called by muse, mutect2, varscan2
- FNBP4 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV55451238, COSV55452092; called by muse, mutect2
- FRAS1 | c.6193G>A p.G2065R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99356561; called by muse, mutect2, varscan2
- FYB2 | c.2097A>T p.Q699H | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV58588891; called by muse, mutect2
- HCFC1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100128496, COSV60073030; called by muse, varscan2
- KLF2 | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1449631953; called by muse, mutect2, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- PKD1L1 | c.5153+1G>C p.X1718_splice | Splice Site (SNP) | VAF 55/121 reads (45%) | catalogued as COSV99219412; called by mutect2, varscan2
- SLC44A3 | c.1576A>T p.T526S (on ENST00000271227 / NM_001114106.3; = p.T478S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV54730579; called by muse, mutect2
- UTRN | c.8121G>A p.M2707I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761673306; called by muse, mutect2, varscan2
- ZMYND12 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs904998645; called by muse, mutect2, varscan2
- AP1AR | c.736del p.S246Vfs*36 | Frame Shift Del (DEL) | VAF 51/175 reads (29%) | called by mutect2, pindel, varscan2
- ASTN2 | c.1904T>G p.L635R (on ENST00000313400 / NM_001365069.1; = p.L584R on NM_014010.5) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP295 | c.5275-2A>T p.X1759_splice | Splice Site (SNP) | VAF 19/418 reads (5%) | called by muse, mutect2
- COBLL1 | c.2477C>G p.S826* (on ENST00000392717; = p.S788* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2, varscan2
- GBP2 | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- HNRNPA1 | c.1055_1063+1del p.X352_splice (on ENST00000340913 / NM_031157.4; = p.X300_splice on NM_002136.4) | Splice Site (DEL) | VAF 33/156 reads (21%) | called by mutect2, pindel, varscan2
- IPO9 | c.2574C>G p.V858= | Splice Region (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- KBTBD11 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- LBR | c.166-4C>A | Splice Region (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- LIG3 | c.1743+1G>T p.X581_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- NIPAL2 | c.792G>A p.K264= | Splice Region (SNP) | VAF 67/175 reads (38%) | called by muse, mutect2, varscan2
- NLRP4 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2J3 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- POLR1B | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2575A>T p.K859* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- SUGCT | c.1233C>G p.I411M (on ENST00000335693 / NM_001193313.2; = p.I437M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- TCF4 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 54/137 reads (39%) | called by muse, varscan2
- TMPRSS15 | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TRAF3 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- WDR7 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 124/329 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF184 | c.1697C>A p.T566N | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ANGEL1 | c.280C>T p.L94= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV51875963; called by muse, mutect2
- CDH18 | c.1398T>C p.P466= | Silent (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- DCDC1 | c.1866T>A p.P622= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs1380749334; called by muse, mutect2, varscan2
- RP1 | c.109C>A p.R37= | Silent (SNP) | VAF 19/497 reads (4%) | called by muse, mutect2
- STAG2 | c.792A>G p.L264= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- AC119673.2 | n.163G>A | RNA (SNP) | VAF 8/23 reads (35%) | catalogued as rs1302918831; called by muse, mutect2
- ACSL6 | chr5:131953462 G>A | 3'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- ADA | c.362+75C>A | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- ANKLE2 | c.641-276A>C | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1674+24T>C | Intron (SNP) | VAF 119/259 reads (46%) | called by muse, mutect2, varscan2
- BEND2 | c.*968C>T | 3'UTR (SNP) | VAF 9/13 reads (69%) | catalogued as rs754533033; called by muse, varscan2
- CDRT15P2 | n.377G>T | RNA (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- CHD1 | c.3711-24A>G | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CLIC6 | c.*741T>G | 3'UTR (SNP) | VAF 54/145 reads (37%) | catalogued as rs977098331; called by muse, mutect2, varscan2
- CRB1 | c.4005+1252T>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- CREB5 | c.*3926G>C | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- CYGB | chr17:76538380 G>T | 5'Flank (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- CYP4Z2P | n.1258A>G | RNA (SNP) | VAF 48/120 reads (40%) | catalogued as rs1210343277; called by muse, mutect2, varscan2
- DCC | c.*1307C>T | 3'UTR (SNP) | VAF 18/70 reads (26%) | catalogued as rs982939379; called by muse, mutect2, varscan2
- DLC1 | c.1348+445G>C | Intron (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- DOCK5 | c.*424C>A | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2733A>C | Intron (SNP) | VAF 90/259 reads (35%) | called by muse, mutect2, varscan2
- ENDOU | c.*631T>A | 3'UTR (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*1215_*1246del | 3'UTR (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel
- EPHA10 | c.*1941C>T | 3'UTR (SNP) | VAF 71/182 reads (39%) | catalogued as rs978780818; called by muse, mutect2, varscan2
- EYA4 | c.*265G>C | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- GPNMB | c.541+270C>G | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- IRAG1 | c.*497T>C | 3'UTR (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- KLK7 | chr19:50983972 G>A | 5'Flank (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- LRCH2 | c.*476A>G | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2
- LRRC28 | c.*8T>A | 3'UTR (SNP) | VAF 81/217 reads (37%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:16052030 C>A | 3'Flank (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- MAP4 | c.*9T>G | 3'UTR (SNP) | VAF 94/211 reads (45%) | called by muse, mutect2, varscan2
- METTL25 | c.1478+275A>G | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2
- MICAL3 | c.2241+6497G>C | Intron (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- MTERF4 | c.-19C>G | 5'UTR (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*1882G>T | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- NRXN1 | c.*576C>T | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- OR2AK2 | c.-101T>A | 5'UTR (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*3146A>G | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- PFKFB2 | chr1:207080747 G>T | 3'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- PRDM5 | c.*2968T>A | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- RBMS1 | c.901-914del | Intron (DEL) | VAF 64/184 reads (35%) | called by mutect2, pindel, varscan2
- RFX4 | c.-85C>T | 5'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- RPS3 | c.256-68G>A | Intron (SNP) | VAF 67/111 reads (60%) | catalogued as COSV53705307; called by muse, mutect2, varscan2
- SDC3 | c.*130G>C | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- SLC17A5 | c.*1697G>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- SNX30 | c.*608T>G | 3'UTR (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- SSBP2 | c.*677A>G | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- STAG3L4 | n.343C>T | RNA (SNP) | VAF 19/446 reads (4%) | called by muse, mutect2
- TCF3 | c.1823-360G>A | Intron (SNP) | VAF 6/86 reads (7%) | catalogued as rs1343913266; called by muse, mutect2
- TLCD1 | chr17:28726846 C>T | 5'Flank (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- TLL2 | c.*1829C>G | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- TMEM19 | c.*2517A>G | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- TSLP | c.*1806G>T | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- TVP23C-CDRT4 | c.*2039T>A | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- ZNF292 | c.*2473G>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ZNF391 | c.*1277C>T | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- ZNF609 | c.747+663T>A | Intron (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- ZNF782 | c.*751_*755del | 3'UTR (DEL) | VAF 36/92 reads (39%) | called by mutect2, varscan2
